Somatic mutation profile of tumor specimen MMRF_1687_1_BM_CD138pos (aliquot MMRF_1687_1_BM_CD138pos_T2_KBS5U_K11923) from MMRF case MMRF_1687, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.8 years (28,409 days).
Specimen MMRF_1687_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0504511e-cc53-4981-943a-66b2d2602c37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1687_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1687_1_PB_Whole_C7_KBS5U_K11888; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0889a94d-2941-4d9a-a9f7-9bebc16722b5

The open-access MAF lists 136 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 44, Missense Mutation 44, Silent 15, Intron 14, 5'UTR 5, 5'Flank 4, RNA 3, 3'Flank 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 11/108 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AMER3 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs374506642, COSV100365960; called by muse, mutect2, varscan2
- CATSPERG | c.1970A>T p.Q657L | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1466351899; called by muse, mutect2
- CCDC168 | c.4222C>A p.P1408T | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.45); catalogued as COSV70554596; called by muse, mutect2, varscan2
- CHUK | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs758945642; called by muse, mutect2, varscan2
- CUBN | c.4124T>C p.V1375A | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV100911937; called by muse, mutect2
- ELAC1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as rs373421001; called by muse, mutect2, varscan2
- ENPP4 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs866317961, COSV58090496; called by muse, mutect2, varscan2
- EPHA10 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57621179; called by muse, varscan2
- ERC2 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 77/187 reads (41%) | catalogued as rs1440705306, COSV55612369; called by muse, mutect2, varscan2
- IGHV2-70 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs576362735; called by muse, mutect2, varscan2
- IGLV3-1 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as rs61731687; called by muse, varscan2
- JPH1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.273); catalogued as rs1021102404; called by muse, mutect2, varscan2
- PER2 | c.3111+1G>A p.X1037_splice | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as rs766394652; called by muse, varscan2
- PTPRK | c.2744G>A p.R915Q (on ENST00000368215 / NM_001291984.2; = p.R916Q on NM_002844.4) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs746002316, COSV63898028, COSV63904549; called by muse, mutect2, varscan2
- RB1 | c.2027T>A p.L676* | Nonsense Mutation (SNP) | VAF 41/139 reads (29%) | catalogued as CM034903; called by muse, mutect2, varscan2
- STIM2 | c.2177A>T p.H726L | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.053); catalogued as rs1314161288; called by muse, mutect2, varscan2
- TEKT4 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs1553394530, COSV99726480; called by muse, mutect2, varscan2
- TMTC4 | c.2089C>T p.H697Y (on ENST00000376234 / NM_001350577.2; = p.H716Y on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60893677; called by muse, mutect2, varscan2
- ZNF609 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100441071; called by muse, mutect2, varscan2
- ZNF691 | c.620G>A p.S207N (on ENST00000372502; = p.S176N on NM_015911.3) | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs1359381281, COSV65289654; called by muse, mutect2, varscan2
- ADAMTS9 | c.1826A>T p.K609I | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- BBC3 | c.499G>A p.V167M (on ENST00000449228 / NM_001127240.3; = p.Q132= on NM_014417.5) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- BPI | c.232G>C p.G78R (on ENST00000262865; = p.G74R on NM_001725.3) | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC168 | c.20043A>C p.Q6681H | Missense Mutation (SNP) | VAF 115/152 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- COL24A1 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL4A6 | c.2245G>C p.A749P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); called by muse, mutect2
- CSPG4 | c.6872G>A p.G2291D | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2
- CYP2D7 | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- FBXO5 | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDE | c.2272C>G p.L758V | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ITGAX | c.640A>G p.S214G | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NR1H2 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR6C4 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 182/377 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- PELO | c.95T>G p.L32R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLCG2 | c.2543T>C p.L848P | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAMHD1 | c.1082A>T p.D361V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SAMHD1 | c.447G>C p.Q149H | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAMHD1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- SGO2 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2
- SRPK2 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D32 | c.1058C>G p.A353G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TP53BP1 | c.3095C>T p.T1032I | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- TRHDE | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- U2SURP | c.505A>T p.N169Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- UBE3B | c.418T>G p.Y140D | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- UBR3 | c.5353T>C p.F1785L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.931); called by muse, mutect2
- WASHC5 | c.3222_3226del p.P1075Cfs*41 | Frame Shift Del (DEL) | VAF 25/40 reads (63%) | called by mutect2, pindel, varscan2
- ZBTB38 | c.1373T>G p.M458R | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.308); called by muse, mutect2
- CELSR1 | c.1146G>A p.S382= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as rs1392677432, COSV53089505; called by muse, mutect2, varscan2
- CXorf66 | c.957A>G p.A319= | Silent (SNP) | VAF 91/96 reads (95%) | catalogued as COSV65169120; called by muse, mutect2, varscan2
- CYP2D7 | c.1539G>A p.V513= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs746980924; called by muse, mutect2, varscan2
- DGKG | c.399A>C p.A133= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs1420294169; called by muse, mutect2
- GRM7 | c.2367C>A p.P789= | Silent (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- HSPA2 | c.867G>A p.S289= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV55968536, COSV99905090; called by muse, mutect2, varscan2
- IGF1R | c.732C>T p.N244= | Silent (SNP) | VAF 83/184 reads (45%) | catalogued as rs765728831, COSV51279394, COSV51316187; called by muse, mutect2, varscan2
- IGHV2-70 | c.57C>T p.S19= | Silent (SNP) | VAF 41/55 reads (75%) | catalogued as rs554480066; called by muse, mutect2, varscan2
- KLB | c.2826T>C p.F942= | Silent (SNP) | VAF 25/70 reads (36%) | called by muse, varscan2
- NELFA | c.1374G>A p.T458= (on ENST00000542778; = p.T447= on NM_005663.5) | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs1239693383; called by muse, mutect2, varscan2
- NLN | c.1482T>G p.T494= | Silent (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- PTCD1 | c.141C>T p.S47= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs1388397260; called by muse, mutect2
- USP47 | c.3030A>G p.E1010= (on ENST00000399455 / NM_001372095.1; = p.E922= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 44/252 reads (17%) | called by muse, mutect2, varscan2
- XYLT1 | c.1959C>T p.H653= | Silent (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- ZNF665 | c.1791C>T p.V597= (on ENST00000600412; = p.V662= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as rs754623620, COSV101128502, COSV67214826; called by muse, mutect2
- ABCC10 | c.-11-18C>T | Intron (SNP) | VAF 27/173 reads (16%) | called by muse, mutect2, varscan2
- ABHD4 | chr14:22598107 G>A | 5'Flank (SNP) | VAF 42/115 reads (37%) | called by muse, mutect2, varscan2
- AC022748.1 | n.33C>T | RNA (SNP) | VAF 8/45 reads (18%) | catalogued as rs552805701; called by muse, mutect2, varscan2
- ADAMTS17 | c.*1840G>T | 3'UTR (SNP) | VAF 50/122 reads (41%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823313 T>C | 5'Flank (SNP) | VAF 11/23 reads (48%) | catalogued as rs1422212601; called by muse, mutect2, varscan2
- ALX4 | c.*1371G>A | 3'UTR (SNP) | VAF 40/87 reads (46%) | catalogued as rs556404097; called by muse, mutect2, varscan2
- ANGPT2 | c.*3106A>C | 3'UTR (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- ART4 | c.*3201T>C | 3'UTR (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- BLOC1S2 | c.*167C>A | 3'UTR (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- C6orf118 | c.1356+114A>C | Intron (SNP) | VAF 18/32 reads (56%) | called by muse, varscan2
- CACNB2 | c.*1383C>T | 3'UTR (SNP) | VAF 49/105 reads (47%) | catalogued as rs1245327535; called by muse, mutect2, varscan2
- CARF | c.*2662A>T | 3'UTR (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- CASZ1 | c.*914G>C | 3'UTR (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- CDS2 | c.*3710G>A | 3'UTR (SNP) | VAF 22/29 reads (76%) | called by muse, mutect2, varscan2
- CNOT2 | c.1392-354A>C | Intron (SNP) | VAF 27/142 reads (19%) | called by muse, mutect2, varscan2
- CNP | c.*260A>C | 3'UTR (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- COQ7 | c.*640G>A | 3'UTR (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- DENND2A | c.*254T>C | 3'UTR (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- DIAPH1 | c.*894del | 3'UTR (DEL) | VAF 43/123 reads (35%) | called by mutect2, pindel, varscan2
- DYSF | c.3844-36A>T | Intron (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- EIF4A2 | c.209-3dup | Intron (INS) | VAF 18/140 reads (13%) | called by mutect2, varscan2
- ERCC6 | c.1398-89T>A | Intron (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- FCHSD2 | c.*868G>A | 3'UTR (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- FKBP14 | c.*4093A>C | 3'UTR (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- GNAI1 | c.*1587A>C | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- GPATCH2 | c.-116G>T | 5'UTR (SNP) | VAF 127/290 reads (44%) | called by muse, mutect2, varscan2
- GXYLT1 | c.*951A>G | 3'UTR (SNP) | VAF 78/178 reads (44%) | catalogued as rs1191583918; called by muse, mutect2, varscan2
- HECW1 | c.*1472G>A | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- HIP1 | c.*3201A>C | 3'UTR (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- HLA-DPB2 | n.326del | RNA (DEL) | VAF 44/131 reads (34%) | called by mutect2, pindel, varscan2
- HS3ST3B1 | c.*1504G>A | 3'UTR (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- IL15 | c.*388T>C | 3'UTR (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- JAZF1 | c.*1775T>G | 3'UTR (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- KIRREL3 | chr11:127003593 C>T | 5'Flank (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- KRT32 | c.*295G>T | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- LCOR | chr10:96959178 T>G | 3'Flank (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- MACF1 | c.221-26087G>A | Intron (SNP) | VAF 26/174 reads (15%) | catalogued as rs533097564; called by muse, mutect2, varscan2
- MAST4 | c.675-49558A>T | Intron (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- MEP1B | c.*150C>T | 3'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- MMP17 | c.423-341C>T | Intron (SNP) | VAF 42/103 reads (41%) | called by muse, mutect2, varscan2
- NAALADL2 | c.*384A>G | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- NLN | c.*3017T>A | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- OR2L2 | chr1:248039433 T>A | 3'Flank (SNP) | VAF 15/39 reads (38%) | called by muse, varscan2
- PDZRN3 | c.*356C>A | 3'UTR (SNP) | VAF 54/142 reads (38%) | called by muse, mutect2, varscan2
- PHC3 | c.*1908A>G | 3'UTR (SNP) | VAF 21/106 reads (20%) | catalogued as rs1449602100; called by muse, mutect2, varscan2
- PLBD1 | c.-70T>C | 5'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- PRMT8 | c.418-35del | Intron (DEL) | VAF 58/114 reads (51%) | called by mutect2, varscan2
- PTCD1 | c.*2899A>T | 3'UTR (SNP) | VAF 50/119 reads (42%) | called by mutect2, varscan2
- PTPN9 | c.*1095A>C | 3'UTR (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- PUM2 | c.*332T>C | 3'UTR (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- RASSF5 | c.*1177G>C | 3'UTR (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- SLC15A4 | c.*286T>A | 3'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- SLC3A2 | c.994-468G>A | Intron (SNP) | VAF 8/65 reads (12%) | catalogued as rs564418350; called by muse, mutect2, varscan2
- SMC1A | c.*4495C>T | 3'UTR (SNP) | VAF 22/26 reads (85%) | called by muse, mutect2, varscan2
- TAOK3 | c.*875C>G | 3'UTR (SNP) | VAF 10/45 reads (22%) | called by mutect2, varscan2
- TAOK3 | c.*873del | 3'UTR (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- TGOLN2 | c.1308+356G>C | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- TMEM17 | c.319-46A>C | Intron (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975356 A>C | 5'Flank (SNP) | VAF 72/81 reads (89%) | called by muse, mutect2, varscan2
- TMSB4X | c.*32T>G | 3'UTR (SNP) | VAF 26/37 reads (70%) | called by muse, varscan2
- TMSB4X | c.*79T>C | 3'UTR (SNP) | VAF 29/37 reads (78%) | called by muse, varscan2
- TNFSF13 | c.*411A>G | 3'UTR (SNP) | VAF 104/234 reads (44%) | catalogued as rs1468743382; called by muse, mutect2, varscan2
- TRIM9 | c.*358G>A | 3'UTR (SNP) | VAF 26/37 reads (70%) | called by muse, mutect2, varscan2
- UHRF2 | c.1498-1456C>A | Intron (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- WASHC4 | c.-20C>T | 5'UTR (SNP) | VAF 45/93 reads (48%) | catalogued as rs766686209; called by muse, mutect2, varscan2
- WIPF2 | c.*3082C>T | 3'UTR (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- YY1AP1 | c.*165A>C | 3'UTR (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- ZBTB43 | c.*970G>A | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.*4474T>C | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- ZNF134 | c.-25G>A | 5'UTR (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- ZNF286B | n.1084G>A | RNA (SNP) | VAF 76/184 reads (41%) | called by muse, mutect2, varscan2
- ZNF608 | c.-249C>T | 5'UTR (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
